Somatic mutation profile of tumor specimen TCGA-DD-AAE8-01A (aliquot TCGA-DD-AAE8-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 45.3 years (16,549 days).
Specimen TCGA-DD-AAE8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d70fb887-689c-43da-b744-f5c4151a42a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE8-10A (Blood Derived Normal), aliquot TCGA-DD-AAE8-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16b45a2b-ecb4-44eb-8a4a-a6f3625bfbc2

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Frame Shift Del 2, RNA 2, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778114016, CM014539, COSV55624106, COSV99737274; ClinVar: pathogenic; called by muse, mutect2
- ACAP2 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs760720158, COSV100461275; called by muse, mutect2, varscan2
- ALB | c.186T>G p.D62E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763937998, COSV99890493; called by muse, mutect2, varscan2
- ANKRD9 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs1450786892, COSV99743512; called by muse, mutect2
- ARGFX | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100544041; called by muse, mutect2, varscan2
- ARMCX1 | c.422G>C p.S141T | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); catalogued as COSV100863147, COSV100863165; called by muse, mutect2, varscan2
- CD8B | c.104A>T p.K35M | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100514340; called by muse, mutect2, varscan2
- CEP57L1 | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1248231743, COSV100425660, COSV61245545; called by muse, mutect2, varscan2
- CRYBG2 | c.3761T>C p.V1254A | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV100366187; called by muse, mutect2
- DNAH9 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.346); catalogued as COSV52360529; called by muse, mutect2
- DUSP8 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs762127578, COSV100524195; called by muse, mutect2, varscan2
- EEF2K | c.1960G>A p.G654S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs746995048, COSV53784313, COSV99532456; called by muse, mutect2, varscan2
- EFNB2 | c.328T>A p.F110I | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99808491; called by muse, mutect2
- ELMO2 | c.1409T>A p.F470Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV99281338; called by muse, mutect2, varscan2
- FCRL2 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 85/415 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV100829789; called by muse, mutect2, varscan2
- GZMH | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV99361779; called by muse, varscan2
- HMCN1 | c.7053G>T p.K2351N | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99622743; called by muse, mutect2
- IBTK | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.32); catalogued as COSV100089859; called by muse, mutect2, varscan2
- IRX1 | c.639C>G p.D213E | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV100116152; called by muse, mutect2, varscan2
- ITGB2 | c.1084C>A p.P362T (on ENST00000302347; = p.P338T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV100185508; called by muse, mutect2, varscan2
- LMOD1 | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100939067; called by muse, mutect2, varscan2
- LPAR6 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.605); catalogued as COSV99922688; called by muse, mutect2
- NDUFAF1 | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99531282; called by muse, mutect2, varscan2
- NFYB | c.208A>C p.N70H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV99527062; called by muse, mutect2, varscan2
- NID2 | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99355780; called by muse, mutect2, varscan2
- NRXN1 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60508639; called by muse, mutect2, varscan2
- NRXN1 | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs1420356542, COSV100452676; called by muse, mutect2, varscan2
- PLD4 | c.336C>A p.S112R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV101190416; called by muse, mutect2, varscan2
- PLEKHG1 | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs202129963, COSV100651415; called by muse, mutect2
- PNRC1 | c.651A>C p.K217N | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100259712; called by muse, mutect2
- PRDM14 | c.1250A>C p.K417T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52575355; called by muse, mutect2, varscan2
- RGS12 | c.555T>A p.S185R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV100374557; called by muse, mutect2, varscan2
- RPS6KA6 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99423918; called by muse, mutect2, varscan2
- RYR3 | c.14161G>T p.V4721L (on ENST00000389232; = p.V4722L on NM_001036.6) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV101211814; called by muse, mutect2, varscan2
- SLC2A13 | c.1831A>G p.N611D | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV55129552; called by muse, mutect2, varscan2
- SLC41A3 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.271); catalogued as COSV100259293; called by muse, mutect2, varscan2
- SLITRK5 | c.1196A>T p.E399V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100280119; called by muse, mutect2, varscan2
- SPHK1 | c.1048G>A p.V350M (on ENST00000392496 / NM_001355139.2; = p.V364M on NM_021972.4) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs55648239, COSV100039101; called by muse, mutect2, varscan2
- SPTBN4 | c.6758A>T p.E2253V | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100149746; called by muse, mutect2
- STK39 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100596188; called by muse, mutect2, varscan2
- SYCP1 | c.238-1G>A p.X80_splice | Splice Site (SNP) | VAF 61/247 reads (25%) | catalogued as COSV101050706; called by muse, mutect2, varscan2
- TCAIM | c.1127A>T p.Y376F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV100703121; called by muse, mutect2, varscan2
- TDRD5 | c.2558C>T p.T853I | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99675217; called by muse, mutect2, varscan2
- TPI1 | c.356G>C p.G119A (on ENST00000229270; = p.G82A on NM_000365.6) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV99222765, COSV99223020; called by muse, mutect2
- TRAPPC6A | c.220T>C p.W74R (on ENST00000585934 / NM_001270891.2; = p.W88R on NM_024108.3) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99135262; called by muse, mutect2, varscan2
- VAC14 | c.1901C>G p.S634C | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV99934056; called by muse, mutect2
- YTHDC1 | c.2174A>C p.Y725S (on ENST00000344157 / NM_001031732.4; = p.Y707S on NM_133370.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100704566; called by muse, mutect2, varscan2
- ZBTB16 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100250782; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs965851355, COSV100459968; called by muse, mutect2, varscan2
- ZNF248 | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100627446, COSV61997424; called by muse, mutect2
- ANAPC1 | c.4191del p.F1398Lfs*2 | Frame Shift Del (DEL) | VAF 55/221 reads (25%) | called by mutect2, varscan2
- TP53 | c.905_915del p.G302Afs*31 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- ADGRF4 | c.919T>C p.L307= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs1166060613, COSV99347904; called by muse, mutect2
- BRF1 | c.162G>A p.V54= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100526730; called by muse, mutect2, varscan2
- CMTR2 | c.1875A>G p.L625= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs1175084623, COSV100578940; called by muse, mutect2, varscan2
- FAM174A | c.300C>T p.A100= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV100444197; called by muse, mutect2, varscan2
- MAP4K4 | c.3111G>A p.L1037= (on ENST00000347699 / NM_001242559.2; = p.L955= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100153254; called by muse, mutect2, varscan2
- MRGPRF | c.822C>T p.Y274= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs144312357; called by muse, mutect2, varscan2
- MUC4 | c.16089C>T p.S5363= (on ENST00000463781 / NM_018406.7; = p.S1127= on NM_004532.6) | Silent (SNP) | VAF 16/278 reads (6%) | catalogued as COSV100203209; called by muse, mutect2
- PMM1 | c.561C>T p.I187= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV53448703, COSV99347996; called by muse, mutect2, varscan2
- PRKAR2B | c.1152T>C p.L384= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99707810; called by muse, mutect2, varscan2
- RRM1 | c.2349T>C p.N783= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1209180851, COSV100331199; called by muse, mutect2, varscan2
- SMARCAL1 | c.1254A>C p.P418= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100619700; called by muse, mutect2, varscan2
- TBC1D32 | c.2058T>C p.H686= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV99249195; called by muse, mutect2
- TEX15 | c.7422G>T p.G2474= (on ENST00000256246; = p.G2857= on NM_001350162.2) | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99820583; called by muse, mutect2, varscan2
- TRPC7 | c.2370A>G p.R790= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs749498066, COSV100725365; called by muse, mutect2, varscan2
- WNK2 | c.5160T>A p.P1720= (on ENST00000297954 / NM_001282394.1; = p.P1683= on NM_006648.3) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99940624; called by muse, mutect2
- COL18A1-AS1 | n.1731A>C | RNA (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101181662; called by muse, mutect2
- DCHS2 | n.6854C>A | RNA (SNP) | VAF 67/151 reads (44%) | catalogued as COSV100600902; called by muse, mutect2, varscan2
- PDGFD | c.*2A>G | 3'UTR (SNP) | VAF 28/108 reads (26%) | catalogued as rs919643712, COSV100157470; called by muse, mutect2
- ZNF585A | c.*2A>G | 3'UTR (SNP) | VAF 8/89 reads (9%) | catalogued as COSV53068175; called by muse, mutect2
